Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KH, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KH-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

Page 1 of 4

REPORT Tel:

Clinical Consultant & Location

Sex

Unit No

This Copy For:

SPECIMEN

Left globe

CLINICAL DETAILS

Left choroidal melanoma causing visual field defect since

CT scan of liver and chest showed multiple lesions, ?
aetiology.

Tumour extending pre ora and involving ciliary body between
9 and 10 o'clock.

See diagram.

Largest diameter 16.9mm. Thickness 12.4mm. Pre ora.

MACROSCOPIC DESCRIPTION

An intact left eye.

Dimensions: Axial 24.5mm, Horizontal 24mm, Vertical 24.5mm

Cornea: Horizontal 11mm, Vertical 11mm

Optic nerve

Length 7mm, Diameter 4mm

Pupil: very slightly oval

On trans-illumination, slight irregularity on iris at 9
o'clock. A large shadow is seen occupying lateral part of he
eye approximately 21 x 16mm.

Plane of section: horizontal

Intraocular description:

A large collar stud, grey mass is seen on the lateral side.
LBD = 16mm, Height 13.5mm extending from the ciliary body to
approximately 8mm of the optic disc.

MICROSCOPY

Sections show a predominantly amelanotic ciliochoroidal
melanoma of mixed cell type (proportion of epithelioid cells
up to 15%). The number of mitosis is approximately 2/40 high

*ICD-6-3
Melanoma, epithelioid & spindle cell
mixed 8776/3
Site: Overlapping lesion of eye & adnexa
069.8
JTD 1/17/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

power fields. The microvasculature of the melanoma is prominent, and closed loops are present in the planes of section. The lymphocytic infiltrate within the tumour is minimal. Tumour necrosis is not seen. There is focal tumour extension into the sclera through both scleral lamellae and a nerve channel. Although the tumour extends very close to the trabecular meshwork, no ring pattern of spread or involvement of anterior chamber angle is noted. Tumour cells are not seen at the resection margins or sections of optic nerve and vortex veins examined.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body away from the tumour appears atrophic with hyalinisation of ciliary processes. The lens is displaced by the tumour and shows degenerative changes. Retina adjacent to the tumour is slightly atrophic and, as expected for a collar stud tumour, Bruch's membrane appears breached in the sections examined.

DIAGNOSIS

Left eye, enucleation: Ciliochoroidal melanoma of mixed cell type (predominance of spindle cells).

COMMENT

Immunohistochemistry will be carried out. Molecular genetic examination of DNA extracted from the tumour cells will also be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow in due course.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

Reported:

Pathologist:

Electronically Verified:

[page 3 of 3]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

loss of chromosome 1p, monosomy 3, partial loss of chromosome 6p and gains in chromosome 8q.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	No
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	2 /40 HPF
DIFFUSE MELANOMA	No
SPREAD	1= No
CLEARANCE	2= Adequate

Reported: [REDACTED]

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

Criteria	11/6/13	Yes	No
Reviewer Initials: [REDACTED]	Date Reviewed: 11/6/13		

Source: NCI Genomic Data Commons file 4f93dd69-1da4-4c24-99c2-eefead42d9ef (TCGA-VD-A8KH.0032F50D-7E01-438A-979B-CAF5D65419DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).